Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8636, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8636-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Component Results

SURGICAL PANEL:

Final Report

DIAGNOSIS

A) LIVER, BIOPSY:

1. Nonspecific subcapsular fibrotic nodule with calcification
2. Unremarkable background liver
3. Negative for neoplasm

B) PERITONEUM, PERICOLONIC TISSUE, BIOPSY:

Metastatic poorly-differentiated adenocarcinoma, compatible with pancreatic primary

C) PERITONEUM, PERIGASTRIC TISSUE, BIOPSY:

1. Mild nonspecific peritonitis
2. Negative for neoplasm

D) PANCREAS, DISTAL PANCREATECTOMY:

1. Invasive poorly-differentiated pancreatic ductal adenocarcinoma, featuring:
- a. Size: 9 x 8 x 3.2 cm
- b. Extent of invasion: Invades peripancreatic soft tissues with extension to colon wall and diaphragm
- c. Margins: Positive, radial attachments to colon and diaphragm
- d. Perineural invasion: Present
- e. Angiolymphatic invasion: Present
- f. See staging parameters
2. Background pancreas, including pancreatic transection margin is normal
3. Two lymph nodes, peripancreatic, negative for neoplasm (0/2)
4. Three accessory splenic nodules, two positive for adenocarcinoma

PANCREATIC CANCER STAGING PARAMETERS***

Case number: Patient name:

Final TNM: pT3N0M1

stage: IV

MACROSCOPIC

SPECIMEN TYPE

Partial pancreatectomy, Tail

TUMOR SITE

Pancreatic tail

TUMOR SIZE

9 X 8 X 3.2 cm

MICROSCOPIC

HISTOLOGIC TYPE

Ductal Adenocarcinoma

HISTOLOGIC GRADE

G3: (poorly differentiated) of G4

[page 2 of 3]
[REDACTED]

MARGINS - PANCREATICO DUODENECTOMY

Involved by invasive carcinoma

Location(s): Radial margins at attachment sites to diaphragm
and colon (surgical correlation)

LYMPHATIC/VASCULAR INVASION

Present: Lymph-vascular invasion present/identified

PERINEURAL INVASION

Present

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor extends beyond the pancreas but without involvement
of the celiac axis or the superior mesenteric artery)

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 2

Total positive nodes: 0

DISTANT METASTASIS

pM1. (Distant metastasis): Colon, diaphragm, accessory
splenic nodules

PATHOLOGIC STAGE SUMMARY

Final TNM: pT3N0M1

[REDACTED] stage: IV

Attending Pathologist: [REDACTED]
[REDACTED]

CLINICAL INFORMATION

Pancreatic cyst

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Liver biopsy, tumor

The specimen is received fresh labeled "liver biopsy." It consists of a 0.4
cm white-tan firm calcified nodule with adjacent liver parenchyma. It is
entirely submitted on one chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Liver with
calcified nodule; no malignancy." is rendered by [REDACTED]
[REDACTED]

B) SOURCE: Pericolonic tissue

The specimen is received labeled "pericolonic tissue." It consists of a 0.9
x 0.2 x 0.1 cm thin strip of soft red-tan tissue, submitted in toto on one
block for frozen microscopy.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION:

"Adenocarcinoma." is rendered by [REDACTED] consultation with [REDACTED]
[REDACTED]
[REDACTED]

C) SOURCE: Perigastric tissue

Received fresh labeled "perigastric tissue" is a 0.2 cm tan-red tissue
fragment entirely submitted on one chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Granulation
tissue. No malignancy. Pending permanents." is rendered by [REDACTED]
[REDACTED]

D) SOURCE: Pancreas, distal
[REDACTED]
[REDACTED]

[page 3 of 3]
[REDACTED]

Received fresh labeled "distal pancreas" are two separate portions of pancreas. The first is the true proximal portion of the pancreas and measures 3 cm in length and 3 cm in diameter. The true margin staple line is removed and that portion of the tissue is submitted en face on chuck #1 for frozen section diagnosis.

This portion of tissue is sectioned. Cut section of the parenchyma reveals lobulated yellow tissue without a discrete mass or lesion. No fat is attached.

The second fragment of pancreas with attached firm tissue and omentum measures 9 x 7.5 x 4.5 cm. The attached omentum measures 8 x 8 x 2 cm. The anterior portion of the specimen was attached per the surgeon to the diaphragm and the soft tissue is inked red. The posterior aspect is ragged and this is where the colon and stomach were attached to the pancreas, and is inked black. The specimen is sectioned from proximal to distal revealing total replacement of the soft tissue by white-tan slightly heterogeneous presumed tumor measuring 9 x 8 x 3.2 cm. The pancreatic duct is obliterated and normal appearing parenchyma is only found on the proximal most aspect. A representative portion of the presumed tumor is submitted on chuck #2 for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Pancreas margin negative. Mass is adenocarcinoma." is rendered by [REDACTED]

NOTE: Tissue is taken for possible ancillary studies. The tumor extends to the red and black ink of the soft tissue. The hemorrhagic soft tissue distally may represent splenic riffs or lymphoid tissue. The omentum is searched revealing no grossly identifiable lymph nodes. The peripancreatic fat is searched revealing five hemorrhagic possible 0.4-1.2 cm lymph nodes.

Representative sections are submitted labeled:

- 1-2. Frozen section
- 3-5. Representative normal proximal pancreas
- 6-7. Tumor and red ink attachment of diaphragm
- 8-9. Posterior aspect of tumor to attached colon and stomach
- 10-11. Random tumor
12. Tumor near previous spleen
13. One lymph node sectioned
14. Two lymph nodes
15. Two lymph nodes
- 16-18. Remainder of pancreatic fat

This case is accessioned in FileMaker Pro.

Gross dictation by: [REDACTED]

MICROSCOPIC

A-D) The microscopic appearance substantiates the diagnosis.

Dictation by: [REDACTED] transcribed by [REDACTED]

[REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] on [REDACTED] Lab and Collection Information

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 5b79cb9b-19c9-4091-9966-e87ad41c0238 (TCGA-HZ-8636.F19D603C-C3CB-4173-ABE1-B96AF4C5331E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).